Somatic mutation profile of tumor specimen MP2PRT-PAUMSX-TMP1-A (aliquot MP2PRT-PAUMSX-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUMSX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,261 days).
Specimen MP2PRT-PAUMSX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a31442d0-7146-443b-a68b-986853b1938d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMSX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMSX-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc4d08a8-a5c8-429e-8432-04cd66c1c49a

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 177/403 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1517A>C p.Q506P | Missense Mutation (SNP) | VAF 199/459 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs397507548, CM031338, COSV61007665; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP1 | c.9797C>T p.T3266M | Missense Mutation (SNP) | VAF 240/560 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as rs569713960; called by muse, mutect2, varscan2
- TENM3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 225/750 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.316); catalogued as rs373531186; called by muse, mutect2, varscan2
- NXN | c.607C>G p.H203D | Missense Mutation (SNP) | VAF 31/550 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PDHA2 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 218/695 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LRAT | c.93C>G p.G31= | Silent (SNP) | VAF 191/671 reads (28%) | catalogued as COSV60476718; called by muse, mutect2, varscan2
- NRG3 | c.1272C>A p.V424= | Silent (SNP) | VAF 137/496 reads (28%) | called by muse, mutect2, varscan2
- NTRK3 | c.2286G>A p.E762= (on ENST00000360948 / NM_001012338.2; = p.E748= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/641 reads (27%) | catalogued as COSV62305415; called by muse, mutect2, varscan2
